Somatic mutation profile of tumor specimen TCGA-CS-5390-01A (aliquot TCGA-CS-5390-01A-02D-1468-08) from TCGA case TCGA-CS-5390, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 47.8 years (17,460 days).
Specimen TCGA-CS-5390-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bedf9a3d-3e0c-4337-96e5-47023a4c4444.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CS-5390-10A (Blood Derived Normal), aliquot TCGA-CS-5390-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/162237e2-4863-4b55-94fc-13c6dc568cdf

The open-access MAF lists 45 somatic variants for this specimen: 36 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 8, Frame Shift Del 3, Nonsense Mutation 3, In Frame Del 3, Splice Site 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 39/111 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NOTCH1 | c.1011_1013del p.D338del | In Frame Del (DEL) | VAF 12/30 reads (40%) | hotspot (GDC flag); called by pindel, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 98/150 reads (65%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, varscan2
- AC008676.3 | c.509A>G p.Q170R | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV56638010; called by muse, mutect2, varscan2
- ANGPT4 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.95); catalogued as rs762925133, COSV67922731; called by muse, mutect2, varscan2
- ARMCX1 | c.739G>A p.G247S | Missense Mutation (SNP) | VAF 116/341 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65705338, COSV65705504; called by muse, mutect2, varscan2
- ATG5 | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 81/246 reads (33%) | catalogued as rs1562272472, COSV58347418; called by muse, mutect2, varscan2
- BEND2 | c.875C>A p.A292D | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV66217111; called by muse, mutect2
- C2 | c.2189T>G p.I730S | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV100191304; called by muse, mutect2, varscan2
- CSNK1A1L | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.075); catalogued as rs748596649, COSV65789483, COSV65790082; called by muse, mutect2, varscan2
- DNAH5 | c.12391A>G p.T4131A | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54249215; called by muse, mutect2, varscan2
- FAM50B | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs767093077, COSV66655242; called by muse, mutect2, varscan2
- FAM83A | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52684648, COSV52687811; called by muse, mutect2, varscan2
- FUBP1 | c.544G>T p.G182* | Nonsense Mutation (SNP) | VAF 11/154 reads (7%) | catalogued as COSV53937761; called by muse, mutect2
- HOOK1 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 45/68 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs143143349, COSV64621535; called by muse, mutect2, varscan2
- KCNH7 | c.116G>A p.C39Y | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV59812000; called by muse, mutect2, varscan2
- KMT2A | c.10939A>G p.M3647V | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.22); catalogued as COSV63292096; called by muse, mutect2
- KRT9 | c.986A>T p.E329V | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV55855210; called by muse, mutect2, varscan2
- LRRC7 | c.886C>T p.L296F (on ENST00000651989 / NM_001370785.2; = p.L263F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV50468019, COSV50610652; called by muse, mutect2, varscan2
- MSTN | c.28A>C p.I10L | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as COSV53622031; called by muse, mutect2, varscan2
- NEU1 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV57669015; called by muse, mutect2, varscan2
- NOTCH1 | c.1441+1G>A p.X481_splice | Splice Site (SNP) | VAF 9/88 reads (10%) | catalogued as COSV53052718; called by muse, mutect2
- PCSK6 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776423442, COSV59344320; called by muse, mutect2, varscan2
- STK38 | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 75/230 reads (33%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.91); catalogued as COSV57708838, COSV57709226; called by muse, mutect2, varscan2
- TAF9B | c.133+1G>A p.X45_splice | Splice Site (SNP) | VAF 47/127 reads (37%) | catalogued as rs782493197, COSV59372279; called by muse, mutect2, varscan2
- TTLL5 | c.3526A>G p.I1176V | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV54043203; called by muse, mutect2, varscan2
- UGGT2 | c.4378C>T p.Q1460* | Nonsense Mutation (SNP) | VAF 24/75 reads (32%) | catalogued as COSV65078919; called by muse, mutect2, varscan2
- UTP25 | c.1918C>G p.H640D | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.338); catalogued as COSV71966169; called by muse, mutect2, varscan2
- VPS36 | c.124_126del p.L42del | In Frame Del (DEL) | VAF 8/73 reads (11%) | catalogued as rs763216059; called by pindel, varscan2
- ZNF483 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV58517131; called by muse, mutect2
- APPL1 | c.1966_1969del p.Q656Nfs*13 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel, varscan2
- ARID1B | c.4109del p.P1370Qfs*65 | Frame Shift Del (DEL) | VAF 20/173 reads (12%) | called by mutect2, pindel, varscan2
- CSMD3 | c.10152_10154del p.L3385del (on ENST00000297405 / NM_001363185.1; = p.L3216del on NM_052900.3) | In Frame Del (DEL) | VAF 10/70 reads (14%) | called by mutect2, pindel, varscan2
- ERCC6L2 | c.4071G>C p.K1357N | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SERBP1 | c.309_312del p.G105* | Frame Shift Del (DEL) | VAF 36/134 reads (27%) | called by pindel, varscan2
- SUPT20HL1 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- AGMAT | c.849C>T p.A283= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV65436254; called by muse, mutect2
- AOC1 | c.957C>T p.Y319= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs565010501, COSV62870648, COSV62871134; called by muse, mutect2
- DNAH8 | c.12843G>A p.L4281= | Silent (SNP) | VAF 54/159 reads (34%) | catalogued as COSV59477263; called by muse, mutect2, varscan2
- IGHG1 | c.528G>A p.E176= | Silent (SNP) | VAF 10/254 reads (4%) | catalogued as rs1264749443; called by muse, mutect2
- INO80B | c.36G>A p.G12= | Silent (SNP) | VAF 40/181 reads (22%) | catalogued as rs755933772, COSV99270661; called by muse, mutect2, varscan2
- POTEH | c.372C>T p.D124= | Silent (SNP) | VAF 63/666 reads (9%) | catalogued as rs566364504, COSV100624993, COSV58882058, COSV58886966; called by muse, varscan2
- PPP2R2D | c.165C>T p.G55= | Silent (SNP) | VAF 54/362 reads (15%) | catalogued as rs781954298, COSV71863068; called by muse, mutect2, varscan2
- RSPH4A | c.441A>G p.G147= | Silent (SNP) | VAF 52/129 reads (40%) | catalogued as COSV57636549; called by muse, mutect2, varscan2
- MIR146A | n.78G>C | RNA (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
